Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A110, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A110-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

Collection Date :

Diagnosis:

Liver, partial resection.

- **Well differentiated hepatocellular carcinoma** (grade 1 of 4), surgical margins free.
- Incidental sclerotic subcapsular hemangioma.

Comment:

There is mild parenchymal fibrosis adjacent to the tumor, but the liver at some distance from the tumor shows no evidence for fibrosis or cirrhosis.

Dr. has reviewed this case and concurs with the diagnostic opinion.

Clinical History:

The patient is in for liver resection with the clinical diagnosis of HCC. 1

1CD-0-3
carcinoma, hepatocellular, NOS
8170/3
Site: liver C22.0
7/5/11

Gross Description:

Received is one appropriately labeled container, additionally labeled "liver section". The specimen consists of a 1100 g, 17.5 x 16.5 x 5.4 cm liver resection. The capsule is dark red, smooth and glistening with focal fibrinous adhesions. There are no areas of puckering identified. The surgical margin is inked black. Sectioning exhibits a 4.8 x 4.8 x 4.5 cm, well-circumscribed, encapsulated solitary mass with a soft, variegated red/yellow hemorrhagic cut surface. There are focal cystic areas, each approximately 0.5 cm in greatest diameter. This lesion is 4.8 cm from the black inked surgical resection margin. The lesion is 0.2 cm from the capsule. Located 6.2 cm away from the large mass there is a subcapsular 0.8 x 0.6 x 0.4 cm white nodule with a granular cut surface. This nodule is at least 8 cm from the black inked surgical resection margin. A wedge of normal liver was given for research purposes, a section of tumor and additional section of normal liver was given to Tissue Procurement.

A1 - margin closest to largest mass

A2-A5 - representative mass and adjacent liver

A6 - tan subcapsular nodule

A7 - normal liver

Light Microscopy:

Light microscopic examination is performed.

Signature:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Reviewed Initials:	Date Reviewed: 7/5/11	

Source: NCI Genomic Data Commons file 29fdbb0a-7ae6-434b-936b-b73ef96b6d4e (TCGA-BC-A110.DCC8DAE3-E0AF-4B37-8E5F-A2004ACA1F9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).